Surgical pathology report (de-identified scan), TCGA case TCGA-77-6843, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-6843-01A (Primary Tumor).

HISTORY

No details received.

MACROSCOPIC

Two specimens received.

1: The specimen is labelled "right upper lobe" and consists of an upper lobe measuring 150 x 85 x 50 mm in the fresh state. 15 mm lateral to the bronchial resection margin and hilum, there is a nodular, firm subpleural mass measuring 20 mm in diameter. On sectioning, the mass is pale, fleshy and measures 27 mm in diameter. It underlies a proximal bronchus but is well clear of the bronchial resection margins. [Sections taken; bronchial resection margin and hilar and peribronchial lymph nodes, 1A; tumour with overlying pleura, 1B-1D; section of uninvolved lung, 1E]

2: The specimen is labelled "hilar lymph node" and consists of two pieces of blackened lymph node, each measuring 14 and 8 mm in maximal dimensions. The largest piece is bisected. [Wrapped and blocked in toto, 2A].

MICROSCOPY

1: Sections show a poorly differentiated squamous cell carcinoma. The tumour shows areas of clear cell change. The lesion is subpleural but definite pleural invasion is not identified. Special stains will be performed to assess this. The tumour is also in the region of a bronchus. In this area there appears to be an in situ component. There is focal blood vessel invasion but no lymphatic permeation is seen. Perineural permeation is identified. The lesion is well clear of the bronchial resection margin. No lymph node metastases are seen. The adjacent lung shows evidence of emphysema.

2: A deposit of poorly differentiated carcinoma is present within the lymph node cortex.

SUMMARY

Right upper lobe and hilar lymph nodes:

- 1: Poorly differentiated squamous cell carcinoma; 27 mm in maximal dimension.
- 2: Blood vessel and perineural invasion present but no lymphatic permeation seen.
- 3: No definite pleural invasion identified; clear of bronchial margin.
- 4: Hilar lymph node metastases.
- 5: T1N1MX
-

SUPPLEMENTARY REPORT

Focal neuroendocrine positivity is identified within the tumour with chromogranin, synaptophysin and CD 56. The positive areas appear to be in the better differentiated squamous areas. Therefore the tumour is a poorly differentiated squamous cell carcinoma showing focal neuroendocrine differentiation.

T-28000 M-80703 P1-03000

Copies:

Source: NCI Genomic Data Commons file d102dd9f-9125-4953-9230-101dbc77f032 (TCGA-77-6843.538C9962-002F-4415-B145-DD8710BAA108.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).